Somatic mutation profile of tumor specimen TCGA-D1-A16F-01A (aliquot TCGA-D1-A16F-01A-11D-A12J-09) from TCGA case TCGA-D1-A16F, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 60.9 years (22,242 days).
Specimen TCGA-D1-A16F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3cbc1822-64f1-447c-b4e8-0086c51cd471.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A16F-10A (Blood Derived Normal), aliquot TCGA-D1-A16F-10A-01D-A12J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8c74a0d-fd79-436b-af6b-4e5ab07835f6

The open-access MAF lists 618 somatic variants for this specimen: 474 protein-altering or splice-affecting, 131 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 292, Silent 131, Frame Shift Del 123, Frame Shift Ins 24, Nonsense Mutation 15, Splice Site 7, Splice Region 7, RNA 6, Intron 5, In Frame Del 4, Translation Start Site 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP2A1 | c.2464del p.R822Gfs*49 | Frame Shift Del (DEL) | VAF 8/61 reads (13%) | catalogued as rs751365374, COSV62870629; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CPAMD8 | c.2352del p.R785Efs*32 (on ENST00000651564; = p.R738Efs*32 on NM_015692.5) | Frame Shift Del (DEL) | VAF 5/25 reads (20%) | catalogued as rs756064750; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- G6PD | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs387906468, COSV63703880; ClinVar: pathogenic / other; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 173/400 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NPHS2 | c.467del p.L156Cfs*25 | Frame Shift Del (DEL) | VAF 16/108 reads (15%) | catalogued as rs528833893, CD042219; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 39/149 reads (26%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PNPLA6 | c.3439C>T p.R1147C (on ENST00000414982 / NM_001166111.2; = p.R1099C on NM_006702.5) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs587777854, CM149433, COSV55376524; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.821G>A p.W274* | Nonsense Mutation (SNP) | VAF 58/170 reads (34%) | hotspot (GDC flag); catalogued as rs786204875, CM1010008, CM151667, COSV100909695, COSV64288869; called by muse, mutect2, varscan2
- SLC52A2 | c.551del p.P184Rfs*17 | Frame Shift Del (DEL) | VAF 12/51 reads (24%) | catalogued as rs1554854044; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCA6 | c.3688C>A p.P1230T | Missense Mutation (SNP) | VAF 78/355 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs778377159, COSV52641979, COSV99446453; called by muse, mutect2, varscan2
- ACACB | c.7336G>A p.V2446I | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs551014194, COSV58140968, COSV58142317; called by muse, mutect2, varscan2
- ACO1 | c.1744C>T p.Q582* | Nonsense Mutation (SNP) | VAF 21/187 reads (11%) | catalogued as COSV59382621; called by muse, mutect2, varscan2
- ACP7 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.191); catalogued as rs1039950431, COSV58698636; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1492del p.L498Wfs*87 | Frame Shift Del (DEL) | VAF 17/111 reads (15%) | catalogued as COSV55002867, COSV55005246; called by mutect2, pindel, varscan2
- AFDN | c.3368G>A p.R1123Q | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as rs755200405, COSV60050576; called by muse, mutect2, varscan2
- AGRP | c.320C>T p.T107M | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755684740, COSV52099189; called by muse, mutect2, varscan2
- AHSA1 | c.389C>A p.T130K | Missense Mutation (SNP) | VAF 76/251 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV53632708; called by muse, mutect2, varscan2
- AIFM2 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 75/251 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs755322586, COSV57158731; called by muse, mutect2, varscan2
- AL358113.1 | c.3913C>T p.R1305C | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as rs764463413, COSV61958730; called by muse, mutect2, varscan2
- ALDH3B2 | c.433del p.Q145Rfs*105 | Frame Shift Del (DEL) | VAF 12/73 reads (16%) | catalogued as rs749697103; called by mutect2, varscan2
- ALG13 | c.1676G>A p.S559N | Missense Mutation (SNP) | VAF 100/567 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV52642438; called by muse, mutect2, varscan2
- ALOX12B | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.532); catalogued as rs745541957; called by muse, mutect2
- ANK3 | c.12436G>A p.G4146R (on ENST00000280772 / NM_001320874.2; = p.G667R on NM_001149.3) | Missense Mutation (SNP) | VAF 23/234 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs184370155, COSV55046788; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKIB1 | c.437del p.N146Tfs*12 | Frame Shift Del (DEL) | VAF 26/138 reads (19%) | catalogued as rs201434379; called by mutect2, varscan2
- APAF1 | c.1805del p.N602Tfs*8 (on ENST00000551964 / NM_181861.2; = p.N591Tfs*8 on NM_001160.3) | Frame Shift Del (DEL) | VAF 48/166 reads (29%) | catalogued as rs758129366; called by mutect2, varscan2
- APLP1 | c.537G>C p.E179D | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.394); catalogued as COSV52876370, COSV52878522; called by muse, mutect2, varscan2
- APOB | c.1105C>T p.Q369* | Nonsense Mutation (SNP) | VAF 44/263 reads (17%) | catalogued as COSV99268432; called by muse, mutect2, varscan2
- ARAP1 | c.3634G>A p.V1212M (on ENST00000393609 / NM_001040118.2; = p.V967M on NM_015242.4) | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.782); catalogued as rs1434403166, COSV61993131; called by muse, mutect2, varscan2
- ARAP2 | c.4232C>T p.A1411V | Missense Mutation (SNP) | VAF 10/167 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100395321; called by muse, mutect2
- ARHGAP20 | c.3091A>G p.T1031A | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as COSV52815545; called by muse, mutect2, varscan2
- ARHGEF40 | c.2209del p.A737Pfs*3 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | catalogued as rs749402223; called by mutect2, pindel
- ARHGEF6 | c.230G>A p.C77Y | Missense Mutation (SNP) | VAF 86/437 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV51693946, COSV99166496; called by muse, mutect2, varscan2
- ARSH | c.707T>C p.M236T | Missense Mutation (SNP) | VAF 114/342 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV66963564; called by muse, mutect2, varscan2
- ASB9 | c.306G>A p.W102* | Nonsense Mutation (SNP) | VAF 10/71 reads (14%) | catalogued as COSV66852070; called by muse, mutect2, varscan2
- ASH1L | c.6842G>A p.R2281Q (on ENST00000368346 / NM_001366177.2; = p.R2276Q on NM_018489.3) | Missense Mutation (SNP) | VAF 82/455 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.929); catalogued as rs778226620, COSV64211069; called by muse, mutect2, varscan2
- ATG4D | c.1046-2A>G p.X349_splice | Splice Site (SNP) | VAF 13/93 reads (14%) | catalogued as COSV57265344; called by muse, mutect2, varscan2
- ATM | c.6415_6416del p.E2139Ifs*6 | Frame Shift Del (DEL) | VAF 50/203 reads (25%) | catalogued as rs863225466; called by pindel, varscan2
- ATP2B3 | c.3385C>A p.L1129M | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.363); catalogued as COSV99686046; called by muse, mutect2
- ATP6AP1 | c.1182G>T p.Q394H | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV63896042; called by muse, mutect2, varscan2
- ATP7A | c.1661C>T p.T554I | Missense Mutation (SNP) | VAF 22/581 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100431793; called by muse, mutect2
- B3GALT1 | c.796G>A p.V266I | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs749376311, COSV59909342; called by muse, mutect2, varscan2
- B4GALNT2 | c.667C>A p.P223T | Missense Mutation (SNP) | VAF 28/354 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.162); catalogued as COSV100302808; called by muse, mutect2
- BAZ2B | c.5149G>T p.G1717C | Missense Mutation (SNP) | VAF 30/388 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100600695, COSV100601057; called by muse, mutect2
- BCOR | c.2170A>G p.M724V | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV60713500; called by muse, mutect2, varscan2
- BMP1 | c.1045G>A p.V349M | Missense Mutation (SNP) | VAF 22/183 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.88); catalogued as rs143279632, COSV60481795; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRD8 | c.2250-3del | Splice Region (DEL) | VAF 21/137 reads (15%) | catalogued as rs749043197; called by mutect2, varscan2
- BTBD7 | c.173del p.K58Rfs*44 | Frame Shift Del (DEL) | VAF 14/124 reads (11%) | catalogued as rs752512017; called by mutect2, varscan2
- C16orf92 | c.296G>T p.S99I | Missense Mutation (SNP) | VAF 172/573 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.366); catalogued as COSV54227725; called by muse, mutect2, varscan2
- CACNA1A | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs866087553, COSV64205649; called by muse, mutect2, varscan2
- CACNA1E | c.3214G>A p.V1072I | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as rs553844010, COSV62387517; called by muse, mutect2, varscan2
- CACTIN | c.1384C>T p.R462W | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99698913; called by muse, mutect2, varscan2
- CAMSAP1 | c.3667G>A p.V1223M | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs920214173, COSV56725564; called by muse, mutect2, varscan2
- CASKIN1 | c.1222G>A p.G408S | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.178); catalogued as rs1200237739, COSV58874870; called by muse, mutect2, varscan2
- CBLL2 | c.280C>A p.P94T | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV60369719; called by muse, mutect2, varscan2
- CCAR2 | c.1013C>T p.T338M | Missense Mutation (SNP) | VAF 31/330 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.333); catalogued as rs199827847, COSV100414962; called by muse, mutect2
- CCDC150 | c.3188A>G p.K1063R | Missense Mutation (SNP) | VAF 57/207 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV55876724; called by muse, mutect2, varscan2
- CCDC170 | c.1952C>T p.A651V | Missense Mutation (SNP) | VAF 61/241 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53338252, COSV53343706; called by muse, mutect2, varscan2
- CD7 | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs768642514, COSV100444801, COSV57067938; called by muse, mutect2, varscan2
- CDON | c.1872G>A p.M624I | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV55000458; called by muse, mutect2, varscan2
- CEBPZ | c.2885-3del | Splice Region (DEL) | VAF 10/79 reads (13%) | catalogued as rs375852685; called by mutect2, varscan2
- CEP72 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs145377725; called by muse, mutect2, varscan2
- CERS5 | c.851G>A p.R284Q | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs953964494, COSV58189893; called by muse, mutect2, varscan2
- CHD7 | c.5740C>T p.R1914C | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373823856; called by muse, mutect2
- CHRDL1 | c.1222+1G>A p.X408_splice (on ENST00000372045; = p.X414_splice on NM_145234.4) | Splice Site (SNP) | VAF 117/390 reads (30%) | catalogued as COSV54327103; called by muse, mutect2, varscan2
- CHST12 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs905098497, COSV51676142; called by muse, mutect2, varscan2
- CLPSL2 | c.149A>G p.D50G | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV64610410; called by muse, mutect2, varscan2
- CLUH | c.1769G>A p.R590H (on ENST00000435359; = p.R628H on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.321); catalogued as rs745452744, COSV101425898, COSV70929300, COSV70929554; called by muse, mutect2, varscan2
- CNKSR2 | c.2764T>A p.S922T | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV65329579, COSV65336391; called by muse, mutect2, varscan2
- COL26A1 | c.1306C>A p.Q436K (on ENST00000313669 / NM_001278563.3; = p.Q434K on NM_133457.4) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.007); catalogued as COSV100562105; called by muse, mutect2
- COLEC11 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99363046, COSV99363739; called by muse, varscan2
- CORO7 | c.1957G>A p.A653T | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52032360; called by muse, mutect2, varscan2
- COX4I1 | c.258C>A p.F86L | Missense Mutation (SNP) | VAF 60/223 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as COSV53666322; called by muse, mutect2, varscan2
- COX7A1 | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as COSV53085061; called by muse, mutect2
- CPNE4 | c.389C>A p.S130Y | Missense Mutation (SNP) | VAF 48/160 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as COSV70196930, COSV70197493; called by muse, mutect2, varscan2
- CRISPLD1 | c.1042A>G p.N348D | Missense Mutation (SNP) | VAF 38/326 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.027); catalogued as COSV51551243; called by muse, varscan2
- CUL1 | c.1343A>G p.Q448R | Missense Mutation (SNP) | VAF 35/254 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.503); catalogued as COSV57390866; called by muse, mutect2, varscan2
- CYP39A1 | c.301G>A p.V101I | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as rs540612754, COSV51495108, COSV51495942; called by muse, mutect2, varscan2
- CYP46A1 | c.554C>A p.T185N | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99952909; called by muse, mutect2, varscan2
- DBR1 | c.512T>C p.F171S | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV53430592; called by muse, mutect2, varscan2
- DCP1B | c.1265A>G p.H422R | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.025); catalogued as rs755196890, COSV99767991; called by muse, mutect2
- DEPDC1 | c.248A>G p.H83R | Missense Mutation (SNP) | VAF 59/214 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as rs1342177150, COSV63958678; called by muse, mutect2, varscan2
- DGKH | c.2941G>A p.A981T | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs778461926, COSV54936970, COSV54942411; called by muse, mutect2
- DISP1 | c.3103A>G p.N1035D | Missense Mutation (SNP) | VAF 32/299 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs757026962, COSV52654589; called by muse, mutect2
- DMBT1 | c.2489T>G p.V830G | Missense Mutation (SNP) | VAF 28/210 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV100352556, COSV57552610; called by muse, mutect2, varscan2
- DNAH11 | c.4891G>A p.V1631I | Missense Mutation (SNP) | VAF 56/423 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs766901693, COSV60963386; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOCK10 | c.6332C>T p.A2111V | Missense Mutation (SNP) | VAF 30/245 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs199583328, COSV51422002; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 20/204 reads (10%) | catalogued as rs782552436; called by mutect2, varscan2
- DOCK7 | c.1561C>T p.H521Y | Missense Mutation (SNP) | VAF 28/282 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.349); catalogued as COSV99226178; called by muse, mutect2
- DPP6 | c.550del p.I184Lfs*4 (on ENST00000377770 / NM_001364500.2; = p.I122Lfs*4 on NM_001936.5) | Frame Shift Del (DEL) | VAF 25/167 reads (15%) | catalogued as rs773847741; called by mutect2, varscan2
- DPYSL2 | c.969-1G>A p.X323_splice | Splice Site (SNP) | VAF 6/128 reads (5%) | catalogued as COSV100234264; called by muse, mutect2
- DSP | c.3922C>T p.R1308W | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.803); catalogued as rs144641271; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DST | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 33/197 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773990518, COSV56836031; called by muse, mutect2, varscan2
- DYNC1H1 | c.13775G>T p.W4592L | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100795482; called by muse, mutect2
- ECI2 | c.488C>T p.A163V (on ENST00000380118 / NM_206836.3; = p.A133V on NM_006117.2) | Missense Mutation (SNP) | VAF 53/502 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs149056651, COSV100326868; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2429C>T p.A810V | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV62569472; called by muse, mutect2, varscan2
- EID1 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.776); catalogued as rs1236981975, COSV60114749; called by muse, mutect2, varscan2
- ELAVL3 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV63647258; called by muse, mutect2, varscan2
- EPS8 | c.70T>C p.S24P | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.343); catalogued as rs1257413851, COSV55534069; called by muse, mutect2, varscan2
- FAAH | c.1668G>A p.W556* | Nonsense Mutation (SNP) | VAF 29/206 reads (14%) | catalogued as COSV54545144; called by muse, mutect2, varscan2
- FAM3D | c.586-4_586-3dup | Splice Region (INS) | VAF 35/202 reads (17%) | catalogued as rs1559492634; called by mutect2, varscan2
- FAM71F2 | c.626G>A p.S209N | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.425); catalogued as COSV66352312; called by muse, mutect2, varscan2
- FBF1 | c.1970G>A p.R657Q (on ENST00000586717; = p.R671Q on NM_001319193.1) | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs201543003, COSV59866135; called by muse, mutect2, varscan2
- FBXO47 | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1171455509, COSV100960900; called by muse, mutect2
- FCHSD1 | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 57/187 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1370073246, COSV71301537; called by muse, mutect2, varscan2
- FCRL3 | c.966G>A p.W322* | Nonsense Mutation (SNP) | VAF 24/206 reads (12%) | catalogued as COSV63843587; called by muse, mutect2, varscan2
- FEM1C | c.944C>A p.P315H | Missense Mutation (SNP) | VAF 23/212 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57232307; called by muse, mutect2, varscan2
- FGD1 | c.1516A>G p.N506D | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV100911272; called by muse, mutect2
- FGFR2 | c.323C>G p.T108S | Missense Mutation (SNP) | VAF 35/243 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as COSV60654191; called by muse, mutect2, varscan2
- FGL2 | c.1132G>T p.G378C | Missense Mutation (SNP) | VAF 8/254 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99593202; called by muse, mutect2
- FLG | c.314G>T p.S105I | Missense Mutation (SNP) | VAF 113/611 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.138); catalogued as CD156643, COSV64245175; called by muse, mutect2, varscan2
- FLNC | c.3005G>A p.R1002Q | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.109); catalogued as rs202039743; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FOXC1 | c.446G>A p.G149D | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM063995, COSV101083387; called by muse, mutect2, varscan2
- FOXP2 | c.598-1G>C p.X200_splice | Splice Site (SNP) | VAF 8/32 reads (25%) | catalogued as rs752704782, COSV63481967; ClinVar: uncertain significance; called by mutect2, varscan2
- FRAS1 | c.1898G>A p.R633H | Missense Mutation (SNP) | VAF 28/211 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs954177790, COSV53630167; called by muse, mutect2, varscan2
- FRAS1 | c.9182C>T p.A3061V | Missense Mutation (SNP) | VAF 51/252 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs886059637, COSV53630192; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FRMD5 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.998); catalogued as rs1236617686, COSV68723997; called by muse, varscan2
- FRMD5 | c.643G>A p.V215M | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.978); catalogued as rs371288449; called by muse, mutect2
- FXR1 | c.371del p.N124Ifs*14 | Frame Shift Del (DEL) | VAF 68/214 reads (32%) | catalogued as rs756304971; called by mutect2, varscan2
- FZD2 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.686); catalogued as rs1443411666, COSV59529716; called by muse, mutect2, varscan2
- GBE1 | c.232G>A p.V78I | Missense Mutation (SNP) | VAF 35/261 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as rs760216641, COSV70101278; called by muse, mutect2, varscan2
- GBP4 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.082); catalogued as COSV100864476; called by muse, mutect2
- GCNT4 | c.880dup p.H294Pfs*2 | Frame Shift Ins (INS) | VAF 14/98 reads (14%) | catalogued as rs768450027; called by mutect2, varscan2
- GCSAM | c.529C>T p.H177Y | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV58264045; called by muse, mutect2, varscan2
- GET3 | c.159C>T p.C53= | Splice Region (SNP) | VAF 6/56 reads (11%) | catalogued as rs1409374841, COSV54407337, COSV99662188; called by muse, mutect2, varscan2
- GIGYF2 | c.1625_1626del p.Q542Rfs*9 | Frame Shift Del (DEL) | VAF 33/280 reads (12%) | catalogued as COSV65251771; called by mutect2, pindel, varscan2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 45/416 reads (11%) | catalogued as rs370114090; called by mutect2, varscan2
- GP2 | c.1208C>T p.A403V (on ENST00000381362 / NM_001007240.3; = p.A400V on NM_001502.4) | Missense Mutation (SNP) | VAF 38/222 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56895462; called by muse, mutect2, varscan2
- GPN3 | c.630dup p.F211Ifs*6 | Frame Shift Ins (INS) | VAF 25/211 reads (12%) | catalogued as rs766995173; called by mutect2, pindel, varscan2
- GPR153 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376925598; called by muse, mutect2, varscan2
- GPR179 | c.4274T>C p.L1425S (on ENST00000621958; = p.L1424S on NM_001004334.4) | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs1259320931; called by muse, mutect2
- GRIK1 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 95/290 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.509); catalogued as rs375169701; called by muse, mutect2, varscan2
- GRK2 | c.1250_1252del p.F417del | In Frame Del (DEL) | VAF 20/184 reads (11%) | catalogued as rs781191950; called by mutect2, pindel, varscan2
- GSPT1 | c.325T>C p.Y109H (on ENST00000420576 / NM_001130007.2; = p.Y247H on NM_002094.4) | Missense Mutation (SNP) | VAF 28/483 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101341769; called by muse, mutect2
- GSPT2 | c.322dup p.A108Gfs*15 | Frame Shift Ins (INS) | VAF 12/58 reads (21%) | catalogued as rs398124340; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- GYG1 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 92/315 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1274680720, COSV56048916; called by muse, mutect2, varscan2
- HAPLN4 | c.292G>A p.V98I | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.895); catalogued as COSV52270585; called by muse, mutect2, varscan2
- HDC | c.812A>G p.H271R | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99984351; called by muse, mutect2, varscan2
- HDGFL2 | c.677del p.K226Rfs*45 | Frame Shift Del (DEL) | VAF 9/72 reads (13%) | catalogued as rs1219916331, COSV56682191; called by mutect2, varscan2
- HDLBP | c.3289-3del | Splice Region (DEL) | VAF 28/157 reads (18%) | catalogued as rs778255938; called by mutect2, pindel, varscan2
- HELZ | c.4073G>A p.R1358H | Missense Mutation (SNP) | VAF 72/888 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.987); catalogued as rs1182873617, COSV62377958; called by muse, mutect2
- HERC1 | c.2452C>T p.Q818* | Nonsense Mutation (SNP) | VAF 19/154 reads (12%) | catalogued as COSV71249195; called by muse, mutect2, varscan2
- HERC2 | c.5351G>A p.R1784H | Missense Mutation (SNP) | VAF 104/347 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1377524842, COSV55305580, COSV55338416; called by muse, mutect2, varscan2
- HERC2 | c.3176G>A p.R1059H | Missense Mutation (SNP) | VAF 75/255 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV55305878; called by muse, mutect2, varscan2
- HIVEP1 | c.3334A>G p.M1112V | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1329624726, COSV65103653; called by muse, mutect2
- HK3 | c.1079C>A p.T360N | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.065); catalogued as COSV99459505; called by muse, mutect2
- HNRNPM | c.826G>A p.V276I | Missense Mutation (SNP) | VAF 15/331 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.871); catalogued as COSV57694359; called by muse, mutect2
- HOATZ | c.485A>G p.Q162R (on ENST00000375618 / NM_001100388.1; = p.Q189R on NM_207430.2) | Missense Mutation (SNP) | VAF 77/273 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV60442030; called by muse, mutect2, varscan2
- HOOK3 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.472); catalogued as COSV100296069; called by muse, mutect2
- HTR1E | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 50/270 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1263006902, COSV59506673; called by muse, mutect2, varscan2
- IDO2 | c.704G>A p.R235Q (on ENST00000389060; = p.R248Q on NM_194294.2) | Missense Mutation (SNP) | VAF 72/782 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs775170246, COSV100584990, COSV58427758; called by muse, mutect2
- IFNW1 | c.74A>G p.D25G | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.108); catalogued as COSV66522243; called by muse, mutect2, varscan2
- IFT172 | c.4701C>G p.H1567Q | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as CM150472, COSV51994310, COSV51995134; called by muse, mutect2, varscan2
- IGSF9 | c.154del p.L52Cfs*79 | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | catalogued as rs753928344; called by mutect2, pindel, varscan2
- IL19 | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 16/254 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs560760235, COSV54283916; called by muse, mutect2
- ILDR1 | c.499C>T p.H167Y | Missense Mutation (SNP) | VAF 52/228 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1407047461, COSV56551979; called by muse, mutect2, varscan2
- INPP5D | c.1253dup p.P419Sfs*27 (on ENST00000445964 / NM_001017915.3; = p.P418Sfs*27 on NM_005541.5) | Frame Shift Ins (INS) | VAF 24/119 reads (20%) | catalogued as rs759837481; called by mutect2, varscan2
- INTS6L | c.359del p.L120* | Frame Shift Del (DEL) | VAF 16/154 reads (10%) | catalogued as rs782242788; ClinVar: uncertain significance; called by mutect2, varscan2
- IQGAP1 | c.3324G>T p.E1108D | Missense Mutation (SNP) | VAF 19/200 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as COSV99185403; called by muse, mutect2
- JADE1 | c.1220G>A p.R407Q | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs901860057, COSV56908018; called by muse, mutect2, varscan2
- KANK1 | c.3416A>G p.Y1139C | Missense Mutation (SNP) | VAF 55/180 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371377616; called by muse, mutect2, varscan2
- KANK2 | c.1625C>T p.A542V (on ENST00000586659 / NM_001379562.1; = p.A550V on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/192 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV62009071; called by muse, mutect2, varscan2
- KANK4 | c.2189A>T p.E730V | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs780653427, COSV58093521; called by muse, mutect2, varscan2
- KATNB1 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.145); catalogued as rs529376681, COSV65552015; called by muse, mutect2, varscan2
- KCTD14 | c.454A>G p.M152V | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV100779959; called by muse, mutect2
- KIAA2026 | c.2187del p.A730Qfs*26 | Frame Shift Del (DEL) | VAF 17/81 reads (21%) | catalogued as rs749990720; called by mutect2, varscan2
- KIF26B | c.1601T>C p.V534A | Missense Mutation (SNP) | VAF 31/199 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63642627; called by muse, mutect2, varscan2
- KIF5C | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 20/298 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV101276216; called by muse, mutect2
- KIRREL3 | c.1260del p.I421Sfs*63 | Frame Shift Del (DEL) | VAF 19/98 reads (19%) | catalogued as rs753746325; called by mutect2, pindel, varscan2
- KLF17 | c.351G>C p.M117I | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100955044, COSV64856736; called by muse, mutect2, varscan2
- KLHL12 | c.667C>T p.R223W | Missense Mutation (SNP) | VAF 15/278 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63042651; called by muse, mutect2
- KMT2A | c.5594del p.P1865Qfs*3 | Frame Shift Del (DEL) | VAF 47/328 reads (14%) | catalogued as COSV63286499; called by mutect2, pindel, varscan2
- KRR1 | c.890A>G p.Q297R | Missense Mutation (SNP) | VAF 24/606 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV99875921; called by muse, mutect2
- KRT75 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as rs1444521517, COSV52871736; called by muse, mutect2, varscan2
- KY | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV71018144; called by muse, mutect2, varscan2
- LBR | c.1084G>A p.G362R | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55290526; called by muse, mutect2, varscan2
- LIG3 | c.1192C>T p.Q398* | Nonsense Mutation (SNP) | VAF 6/104 reads (6%) | catalogued as COSV99253254; called by muse, mutect2
- LPP | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 53/191 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as rs147109696; called by muse, mutect2, varscan2
- LRRIQ1 | c.4624A>T p.I1542F | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67828881, COSV67829749, COSV67839512; called by muse, mutect2, varscan2
- LRRN3 | c.1815dup p.C606Mfs*12 | Frame Shift Ins (INS) | VAF 24/70 reads (34%) | catalogued as rs747411092; called by mutect2, varscan2
- LTBP4 | c.4224del p.A1409Hfs*20 (on ENST00000308370 / NM_001042544.1; = p.A1372Hfs*20 on NM_003573.2) | Frame Shift Del (DEL) | VAF 13/113 reads (12%) | catalogued as rs754757253, COSV52588935; called by mutect2, pindel, varscan2
- LYST | c.1826A>G p.Q609R | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.276); catalogued as COSV101090400; called by muse, mutect2
- MADD | c.3763A>G p.K1255E | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.593); catalogued as COSV60627242; called by muse, mutect2, varscan2
- MAGEA12 | c.89C>A p.A30D | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as COSV100757097; called by muse, mutect2, varscan2
- MAGEB6 | c.684G>C p.E228D | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV66872675; called by muse, mutect2, varscan2
- MAK16 | c.432G>T p.R144S | Missense Mutation (SNP) | VAF 163/710 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV64078516; called by muse, mutect2, varscan2
- MAP3K2 | c.1489G>A p.V497I | Missense Mutation (SNP) | VAF 27/198 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.5); catalogued as rs1280449237, COSV61295450; called by muse, mutect2, varscan2
- MAP3K4 | c.1547G>T p.G516V | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.422); catalogued as COSV62336261; called by muse, mutect2, varscan2
- MAPKBP1 | c.2119A>G p.T707A (on ENST00000456763 / NM_001128608.2; = p.T701A on NM_014994.3) | Missense Mutation (SNP) | VAF 104/552 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs568036665, COSV52964870; called by muse, mutect2, varscan2
- MBTPS1 | c.1790del p.N597Mfs*9 | Frame Shift Del (DEL) | VAF 18/102 reads (18%) | catalogued as rs780087229; called by pindel, varscan2
- MCM10 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.648); catalogued as rs533521913, COSV66335743; called by muse, mutect2, varscan2
- MCM7 | c.761C>T p.T254M | Missense Mutation (SNP) | VAF 13/160 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs200587772, COSV99053958; called by muse, mutect2
- MED15 | c.1730C>T p.S577L (on ENST00000263205 / NM_001003891.3; = p.S537L on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as rs1461282663, COSV53031715; called by muse, mutect2, varscan2
- MEGF10 | c.950G>A p.G317D | Missense Mutation (SNP) | VAF 11/291 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99175787; called by muse, mutect2
- MESD | c.632del p.K211Rfs*6 | Frame Shift Del (DEL) | VAF 43/294 reads (15%) | catalogued as rs745891632; called by mutect2, varscan2
- MGAT5B | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as rs1227509593, COSV56927079; called by muse, mutect2, varscan2
- MGST2 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 10/294 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.109); catalogued as COSV99643796; called by muse, mutect2
- MINK1 | c.2668C>T p.R890C | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs777194032, COSV53419124; called by muse, mutect2, varscan2
- MMP1 | c.622A>G p.R208G | Missense Mutation (SNP) | VAF 38/388 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV100188127; called by muse, mutect2
- MNT | c.1391G>A p.G464D | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as rs1237910133, COSV51513203; called by muse, mutect2, varscan2
- MPL | c.289G>T p.D97Y | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV65245959; called by muse, mutect2, varscan2
- MRPS7 | c.331A>G p.M111V | Missense Mutation (SNP) | VAF 77/414 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0.009); catalogued as COSV55453959; called by muse, mutect2, varscan2
- MTMR8 | c.1052T>C p.V351A | Missense Mutation (SNP) | VAF 25/234 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV100878624; called by muse, mutect2, varscan2
- MTSS1 | c.1360G>T p.E454* | Nonsense Mutation (SNP) | VAF 12/174 reads (7%) | catalogued as COSV100275716; called by muse, mutect2
- MYH14 | c.3181C>T p.R1061W | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs397516629, COSV51825622; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH8 | c.5726C>T p.A1909V | Missense Mutation (SNP) | VAF 108/294 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV67959674; called by muse, mutect2, varscan2
- MYO16 | c.289C>A p.L97I | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51807251; called by muse, mutect2, varscan2
- MYO3B | c.3353C>T p.A1118V | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.025); catalogued as COSV58710727; called by muse, mutect2, varscan2
- MYO9B | c.3397G>A p.V1133M | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.374); catalogued as rs200674880, COSV68280760; called by muse, mutect2, varscan2
- NAALADL2 | c.1554del p.N520Mfs*12 | Frame Shift Del (DEL) | VAF 26/188 reads (14%) | catalogued as rs1478908176, COSV69154859; called by mutect2, pindel*, varscan2
- NCEH1 | c.1085C>T p.A362V (on ENST00000538775; = p.A322V on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/183 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56436390; called by muse, mutect2, varscan2
- NCKAP5 | c.4288A>G p.R1430G | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as COSV58461851; called by muse, mutect2, varscan2
- NDST1 | c.1661C>T p.T554M | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55786798, COSV55789178; called by muse, mutect2, varscan2
- NDST3 | c.2167G>A p.E723K | Missense Mutation (SNP) | VAF 15/159 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.3); catalogued as rs759159756, COSV56613650; called by muse, mutect2
- NDUFAF4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 67/216 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60214423; called by muse, mutect2, varscan2
- NEB | c.2476G>A p.A826T | Missense Mutation (SNP) | VAF 58/458 reads (13%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.997); catalogued as rs373705550; called by muse, mutect2, varscan2
- NEURL4 | c.1936G>A p.G646R | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761752309, COSV100224802, COSV59757626; called by muse, mutect2, varscan2
- NKIRAS2 | c.157del p.V53Cfs*78 | Frame Shift Del (DEL) | VAF 20/126 reads (16%) | catalogued as COSV100288809; called by mutect2, pindel, varscan2
- NOB1 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1384426386, COSV99264109; called by muse, mutect2, varscan2
- NOLC1 | c.840del p.K280Nfs*3 | Frame Shift Del (DEL) | VAF 38/358 reads (11%) | catalogued as rs759637346; called by mutect2, varscan2
- NOSTRIN | c.572del p.N191Tfs*9 (on ENST00000317647 / NM_001039724.4; = p.N113Tfs*9 on NM_052946.3) | Frame Shift Del (DEL) | VAF 34/247 reads (14%) | catalogued as rs1282346576; called by mutect2, pindel, varscan2
- NPR2 | c.2803C>A p.L935I | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV52414852; called by muse, mutect2, varscan2
- NUMA1 | c.4450C>T p.R1484C | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771295685, COSV100706672; called by muse, mutect2
- NUP98 | c.1459G>T p.A487S | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); catalogued as COSV61435807; called by muse, mutect2, varscan2
- OLFM1 | c.1198C>T p.R400C (on ENST00000371793 / NM_001282611.2; = p.R382C on NM_014279.5) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs932606104, COSV53280730, COSV53282200; called by muse, mutect2, varscan2
- OMA1 | c.68C>A p.S23Y | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.033); catalogued as COSV62256305; called by muse, mutect2, varscan2
- OR2A42 | c.278T>C p.F93S | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as COSV101195848; called by mutect2, varscan2
- OR52B6 | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 78/568 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV61447655, COSV61448081; called by muse, mutect2, varscan2
- OR7G1 | c.321del p.F107Lfs*24 | Frame Shift Del (DEL) | VAF 91/360 reads (25%) | catalogued as COSV99528442; called by mutect2, pindel, varscan2
- OSBPL8 | c.1809A>G p.I603M | Missense Mutation (SNP) | VAF 98/350 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as COSV53886733; called by muse, mutect2, varscan2
- OSR2 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.997); catalogued as COSV52558102; called by muse, mutect2, varscan2
- OTUD4 | c.2363C>T p.P788L (on ENST00000447906 / NM_001366057.1; = p.P723L on NM_001102653.1) | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs200113018, COSV71382091; called by muse, mutect2, varscan2
- PARP4 | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 58/422 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.071); catalogued as COSV67963213; called by muse, mutect2, varscan2
- PAX3 | c.247G>A p.V83I | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV51342102; called by muse, mutect2, varscan2
- PAXBP1 | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 119/376 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs545150914, COSV51606860; called by muse, mutect2, varscan2
- PBX4 | c.1076C>T p.A359V | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.018); catalogued as COSV52063018; called by muse, mutect2, varscan2
- PCDH15 | c.4213C>T p.R1405C | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148046721, COSV100218567; called by muse, mutect2, varscan2
- PCDHA1 | c.2261G>A p.R754K | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.033); catalogued as rs968810223, COSV65375817; called by muse, mutect2, varscan2
- PCK2 | c.1512del p.F504Lfs*13 | Frame Shift Del (DEL) | VAF 20/82 reads (24%) | catalogued as COSV53748303; called by mutect2, varscan2
- PCOLCE | c.318G>C p.Q106H | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.363); catalogued as COSV99575732; called by muse, mutect2
- PDE4D | c.487C>T p.R163W (on ENST00000340635 / NM_001104631.2; = p.R27W on NM_006203.4) | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs749395945, COSV58969110; called by muse, mutect2, varscan2
- PDZD2 | c.4248del p.S1419Vfs*6 | Frame Shift Del (DEL) | VAF 7/47 reads (15%) | catalogued as rs113511990, COSV56865110; called by mutect2, pindel, varscan2
- PDZD8 | c.2845C>T p.R949C | Missense Mutation (SNP) | VAF 56/225 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1390076508, COSV53692314; called by muse, mutect2, varscan2
- PELI3 | c.37del p.R13Efs*55 | Frame Shift Del (DEL) | VAF 12/81 reads (15%) | catalogued as COSV57857097; called by mutect2, pindel, varscan2
- PGM2 | c.251G>C p.G84A | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV67939284; called by muse, mutect2, varscan2
- PHACTR3 | c.1071G>T p.K357N | Missense Mutation (SNP) | VAF 41/295 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.082); catalogued as COSV63031473; called by muse, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | catalogued as rs769717544; called by mutect2, varscan2
- PIAS2 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs1343665427, COSV61344316; called by muse, mutect2, varscan2
- PIWIL2 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 39/178 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV63252869; called by muse, mutect2, varscan2
- PLCH2 | c.2501G>A p.R834H | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780172563, COSV53946777; called by muse, mutect2, varscan2
- PLEC | c.10234C>T p.R3412C (on ENST00000322810 / NM_201380.4; = p.R3302C on NM_000445.5) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs782733657, COSV59626153, COSV59662168; ClinVar: uncertain significance; called by muse, mutect2
- PLEKHM2 | c.1499C>T p.A500V | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.576); catalogued as COSV65396389; called by muse, mutect2, varscan2
- PLXNC1 | c.3364C>T p.P1122S | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51579722; called by muse, mutect2, varscan2
- PNPLA2 | c.798del p.A267Pfs*53 | Frame Shift Del (DEL) | VAF 8/55 reads (15%) | catalogued as CM108998; called by mutect2, pindel, varscan2
- POLR3GL | c.397C>T p.L133F | Missense Mutation (SNP) | VAF 14/370 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.26); catalogued as rs151149111; called by muse, mutect2
- PPIF | c.232T>C p.F78L | Missense Mutation (SNP) | VAF 37/238 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV56551441; called by muse, mutect2, varscan2
- PPM1B | c.397A>G p.T133A | Missense Mutation (SNP) | VAF 14/289 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1264782655, COSV99175926; called by muse, mutect2
- PPP1R13B | c.2741C>A p.P914H | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52454172; called by muse, mutect2, varscan2
- PPP1R3A | c.1429dup p.I477Nfs*2 | Frame Shift Ins (INS) | VAF 10/68 reads (15%) | catalogued as rs777079549; called by mutect2, varscan2
- PROC | c.1075G>A p.V359I | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0.013); catalogued as rs375912553, CM071938, CM144436; called by muse, mutect2, varscan2
- PRTG | c.3167del p.F1056Sfs*30 | Frame Shift Del (DEL) | VAF 19/114 reads (17%) | catalogued as rs768325902, COSV101221331; called by mutect2, varscan2
- PSMD3 | c.1531C>T p.R511W | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1479095083, COSV52858896; called by muse, mutect2, varscan2
- PTGER4 | c.1057G>A p.G353R | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs764000694, COSV56721944; called by muse, mutect2, varscan2
- PTPRT | c.301C>A p.H101N | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100630873; called by muse, mutect2, varscan2
- PUM1 | c.1159-2A>G p.X387_splice | Splice Site (SNP) | VAF 12/83 reads (14%) | catalogued as COSV57088953; called by muse, mutect2, varscan2
- PVRIG | c.236del p.G79Afs*245 | Frame Shift Del (DEL) | VAF 10/80 reads (13%) | catalogued as rs768997455; called by mutect2, pindel, varscan2
- PXDN | c.2654G>A p.C885Y | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99415131; called by muse, mutect2
- QSER1 | c.5090del p.N1697Mfs*4 (on ENST00000399302; = p.N1826Mfs*4 on NM_001076786.3) | Frame Shift Del (DEL) | VAF 16/133 reads (12%) | catalogued as rs754588466; called by mutect2, varscan2
- RALY | c.827G>A p.R276Q (on ENST00000246194 / NM_016732.3; = p.R260Q on NM_007367.4) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.005); catalogued as rs1053124266, COSV55782355; called by muse, mutect2
- RANBP6 | c.2975C>A p.P992H | Missense Mutation (SNP) | VAF 40/288 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.052); catalogued as COSV52390619; called by muse, mutect2, varscan2
- RARA | c.469T>C p.S157P | Missense Mutation (SNP) | VAF 35/178 reads (20%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.493); catalogued as COSV54194871; called by muse, mutect2, varscan2
- RBFOX2 | c.1268A>T p.Y423F (on ENST00000438146 / NM_001349995.2; = p.T336S on NM_014309.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53263775, COSV53266874; called by muse, mutect2, varscan2
- RBM11 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as COSV68748249; called by muse, mutect2, varscan2
- RBM14 | c.1754G>A p.R585Q | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1052652681, COSV59557880; called by muse, mutect2, varscan2
- RBMS1 | c.23A>G p.Q8R | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.403); catalogued as COSV100817118; called by muse, mutect2, varscan2
- RGS12 | c.3534del p.K1178Nfs*32 | Frame Shift Del (DEL) | VAF 15/85 reads (18%) | catalogued as rs753542639, COSV58750063; called by mutect2, varscan2
- RNF125 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 42/238 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV54186023; called by muse, mutect2, varscan2
- RNF217 | c.1593dup p.Q532Tfs*16 | Frame Shift Ins (INS) | VAF 63/382 reads (16%) | catalogued as rs1413029182; called by mutect2, pindel, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 35/106 reads (33%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNF44 | c.356T>C p.F119S | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV51270333; called by muse, mutect2, varscan2
- ROCK1 | c.3921del p.K1307Nfs*3 | Frame Shift Del (DEL) | VAF 25/195 reads (13%) | catalogued as rs752898741; called by mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 60/157 reads (38%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPP25L | c.91C>T p.R31* | Nonsense Mutation (SNP) | VAF 25/109 reads (23%) | catalogued as COSV52408263; called by muse, mutect2, varscan2
- RYR1 | c.3392G>T p.W1131L | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.475); catalogued as COSV62104215; called by muse, mutect2, varscan2
- S1PR2 | c.643G>A p.V215M | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.905); catalogued as rs773248254, COSV58485410; called by muse, mutect2, varscan2
- SCN4A | c.1366G>A p.A456T | Missense Mutation (SNP) | VAF 52/268 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.419); catalogued as COSV71127980; called by muse, mutect2, varscan2
- SCN7A | c.863A>G p.Y288C | Missense Mutation (SNP) | VAF 69/247 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as rs545067970, COSV69273391; called by muse, mutect2, varscan2
- SDAD1 | c.824del p.K275Rfs*15 | Frame Shift Del (DEL) | VAF 39/211 reads (18%) | catalogued as rs763181092; called by mutect2, pindel, varscan2
- SDK1 | c.2678C>T p.P893L | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as rs201664766, COSV67371199; called by muse, mutect2, varscan2
- SDSL | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61885001; called by muse, mutect2, varscan2
- SEC16A | c.271G>A p.G91S | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.062); catalogued as rs745347813, COSV51527947; called by muse, mutect2
- SEC31B | c.2043A>T p.E681D | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV64845151; called by muse, mutect2, varscan2
- SENP1 | c.1227del p.G410Vfs*4 | Frame Shift Del (DEL) | VAF 50/338 reads (15%) | catalogued as rs750651342; called by mutect2, varscan2
- SERPINC1 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.793); catalogued as rs747142328, CM092275, COSV62930116; called by muse, mutect2, varscan2
- SF3A1 | c.1786G>A p.V596I | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.796); catalogued as COSV53170208; called by muse, mutect2, varscan2
- SFI1 | c.1961C>T p.A654V (on ENST00000400288 / NM_001007467.3; = p.A623V on NM_014775.4) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0.04); catalogued as rs763555843, COSV66289738; called by muse, mutect2, varscan2
- SGCD | c.824C>T p.A275V (on ENST00000435422 / NM_001128209.2; = p.A276V on NM_000337.5) | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100551283; called by muse, mutect2
- SGO1 | c.973del p.M325Cfs*28 | Frame Shift Del (DEL) | VAF 30/242 reads (12%) | catalogued as rs747473028; called by mutect2, varscan2
- SH3TC1 | c.3398_3400del p.F1133del | In Frame Del (DEL) | VAF 40/205 reads (20%) | catalogued as rs776299504; called by mutect2, pindel, varscan2
- SHC3 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 81/282 reads (29%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.971); catalogued as rs575182413, COSV65439698; called by muse, mutect2, varscan2
- SHOX2 | c.60G>T p.K20N | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as COSV55834482; called by muse, mutect2, varscan2
- SIK2 | c.1430G>A p.R477H | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as rs1265486764, COSV59254586; called by muse, mutect2, varscan2
- SLC17A4 | c.1444C>T p.R482* | Nonsense Mutation (SNP) | VAF 26/530 reads (5%) | catalogued as rs375813431, COSV99766186; called by muse, mutect2
- SLC24A4 | c.500A>G p.D167G | Missense Mutation (SNP) | VAF 127/439 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV54117581; called by muse, mutect2, varscan2
- SLC39A4 | c.1850C>T p.P617L (on ENST00000301305 / NM_001374839.1; = p.P592L on NM_017767.3) | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52780153; called by muse, mutect2, varscan2
- SLC39A8 | c.852del p.E285Sfs*8 | Frame Shift Del (DEL) | VAF 36/327 reads (11%) | catalogued as rs1560527212; called by mutect2, pindel, varscan2
- SLC39A9 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 216/651 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV50363149; called by muse, mutect2, varscan2
- SLC6A6 | c.1396G>A p.V466I | Missense Mutation (SNP) | VAF 100/855 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.017); catalogued as rs1351428708, COSV62651299; called by muse, mutect2, varscan2
- SLC9A5 | c.1601G>A p.R534Q | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.357); catalogued as rs781665116, COSV55362534; called by muse, mutect2, varscan2
- SLCO1C1 | c.1233dup p.I412Dfs*37 | Frame Shift Ins (INS) | VAF 97/367 reads (26%) | catalogued as rs766878114; called by mutect2, pindel, varscan2
- SMC6 | c.1159C>T p.R387* | Nonsense Mutation (SNP) | VAF 61/458 reads (13%) | catalogued as rs764336831, COSV61176717; called by muse, mutect2, varscan2
- SNX12 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV52146406; called by muse, mutect2, varscan2
- SORBS2 | c.1561A>G p.K521E | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53008465; called by muse, mutect2, varscan2
- SORL1 | c.5889G>T p.L1963F | Missense Mutation (SNP) | VAF 27/211 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV52758637; called by muse, mutect2, varscan2
- SP100 | c.2563dup p.S855Kfs*11 | Frame Shift Ins (INS) | VAF 12/116 reads (10%) | catalogued as rs1479231987; called by mutect2, pindel
- SPARC | c.329A>C p.K110T | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.392); catalogued as rs1272850274, COSV99163898; called by muse, mutect2
- SRRM4 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.018); catalogued as COSV57431623; called by muse, mutect2
- ST6GAL2 | c.1501G>T p.G501W | Missense Mutation (SNP) | VAF 11/96 reads (11%) | PolyPhen possibly damaging (0.84); catalogued as COSV62416652, COSV62417460, COSV62417694; called by muse, mutect2, varscan2
- STAU1 | c.261dup p.P88Tfs*4 (on ENST00000371856 / NM_001319135.1; = p.P7Tfs*4 on NM_004602.3) | Frame Shift Ins (INS) | VAF 71/548 reads (13%) | catalogued as rs768949309; called by mutect2, varscan2
- STAU2 | c.1091del p.N364Mfs*67 (on ENST00000524300 / NM_001164380.2; = p.N332Mfs*67 on NM_014393.2) | Frame Shift Del (DEL) | VAF 167/679 reads (25%) | catalogued as rs746501298; called by mutect2, varscan2
- STING1 | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs144606267; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SUSD5 | c.1264A>G p.S422G | Missense Mutation (SNP) | VAF 26/282 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100535367; called by muse, mutect2
- SUV39H1 | c.706G>A p.V236M | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV61921096; called by muse, varscan2
- SUV39H1 | c.1163T>C p.L388P | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.593); catalogued as COSV100551860; called by muse, mutect2
- SYMPK | c.1325C>T p.T442M | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV55613920; called by muse, mutect2, varscan2
- SYNE2 | c.19198G>T p.G6400W | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100648555; called by muse, mutect2
- SZT2 | c.2618C>T p.P873L | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65172116; called by muse, mutect2, varscan2
- TCF25 | c.393del p.K131Nfs*17 | Frame Shift Del (DEL) | VAF 32/132 reads (24%) | catalogued as rs748021112; called by mutect2, varscan2
- TENM3 | c.209A>G p.E70G | Missense Mutation (SNP) | VAF 35/192 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV69314411; called by muse, mutect2, varscan2
- TENT5C | c.820T>C p.F274L | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV65616734; called by muse, mutect2, varscan2
- TET3 | c.1445A>G p.E482G | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.69); catalogued as COSV59881957; called by muse, mutect2, varscan2
- TGFBR2 | c.1043G>A p.R348H | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.532); catalogued as rs369450067; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TLR2 | c.2257C>T p.R753W | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs552749059, COSV52607388, COSV52607453; called by muse, mutect2, varscan2
- TLR9 | c.1966C>T p.Q656* | Nonsense Mutation (SNP) | VAF 9/52 reads (17%) | catalogued as COSV62347731; called by muse, mutect2, varscan2
- TMEM132B | c.290T>C p.I97T | Missense Mutation (SNP) | VAF 11/202 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as COSV100171138; called by muse, mutect2
- TMEM237 | c.502G>A p.A168T (on ENST00000409883 / NM_001044385.3; = p.A160T on NM_152388.4) | Missense Mutation (SNP) | VAF 24/302 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.755); catalogued as COSV99636314; called by muse, mutect2
- TMEM94 | c.1787C>T p.A596V | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as COSV58598394; called by muse, mutect2, varscan2
- TNFRSF11B | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 21/170 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756124545, COSV52072559; called by muse, mutect2, varscan2
- TNIK | c.739del p.R247Gfs*7 | Frame Shift Del (DEL) | VAF 39/263 reads (15%) | catalogued as COSV99454139; called by mutect2, pindel, varscan2
- TNXB | c.9386A>T p.D3129V (on ENST00000647633; = p.D2882V on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100926708; called by muse, mutect2
- TOX4 | c.1355C>T p.P452L | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV52970356; called by muse, mutect2, varscan2
- TRIM56 | c.1100G>T p.R367L | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.013); catalogued as COSV100047822; called by muse, mutect2
- TRIO | c.1883T>C p.L628P | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100711051; called by muse, mutect2
- TSPOAP1 | c.4029G>C p.E1343D | Missense Mutation (SNP) | VAF 6/107 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV52112835; called by muse, mutect2
- TTC31 | c.851G>T p.R284M | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.275); catalogued as COSV99282403; called by muse, mutect2
- TTLL2 | c.826G>T p.G276W | Missense Mutation (SNP) | VAF 14/288 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99515001; called by muse, mutect2
- TTLL7 | c.2252G>A p.R751H | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.066); catalogued as rs368937222; called by muse, mutect2, varscan2
- TUBA1A | c.382C>A p.Q128K | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV55498412; called by muse, mutect2, varscan2
- TUBAL3 | c.826A>G p.M276V | Missense Mutation (SNP) | VAF 18/334 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV100990596; called by muse, mutect2
- TVP23A | c.420del p.F140Lfs*7 | Frame Shift Del (DEL) | VAF 20/119 reads (17%) | catalogued as rs760251146; called by mutect2, varscan2
- UBA2 | c.1829G>A p.R610H | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs575391206, COSV55827838; called by muse, mutect2, varscan2
- UBA5 | c.326A>C p.E109A | Missense Mutation (SNP) | VAF 34/300 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53906624, COSV99393432; called by muse, mutect2, varscan2
- UNC13A | c.1346C>T p.A449V | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as rs367702602; called by muse, mutect2, varscan2
- UNC93B1 | c.941C>T p.T314M | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV57097906; called by muse, mutect2, varscan2
- UPF3B | c.566del p.N189Ifs*4 | Frame Shift Del (DEL) | VAF 300/1156 reads (26%) | catalogued as COSV52230474; called by mutect2, pindel, varscan2
- USF3 | c.439del p.I147Lfs*22 | Frame Shift Del (DEL) | VAF 24/173 reads (14%) | catalogued as rs747493460; called by mutect2, varscan2
- UTP15 | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 52/378 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs761103496, COSV57145916; called by muse, mutect2, varscan2
- VEGFB | c.105G>A p.V35= | Splice Region (SNP) | VAF 13/130 reads (10%) | catalogued as COSV58537659; called by muse, mutect2, varscan2
- VPS54 | c.71T>A p.V24E | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV55443115; called by muse, mutect2, varscan2
- WASHC2A | c.291+1G>A p.X97_splice | Splice Site (SNP) | VAF 50/466 reads (11%) | catalogued as COSV50954756; called by muse, mutect2
- WDR37 | c.235+1G>A p.X79_splice | Splice Site (SNP) | VAF 48/176 reads (27%) | catalogued as COSV54130447; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 17/92 reads (18%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WSCD1 | c.851A>G p.E284G | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100496864; called by muse, mutect2
- XK | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 17/210 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV101064808; called by muse, mutect2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | catalogued as rs779864368; called by mutect2, pindel, varscan2
- ZBED4 | c.2033A>G p.N678S | Missense Mutation (SNP) | VAF 21/212 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.408); catalogued as COSV99351801; called by muse, mutect2
- ZBED4 | c.3385G>A p.V1129I | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.241); catalogued as rs780399671; called by muse, mutect2, varscan2
- ZBED9 | c.665T>C p.M222T | Missense Mutation (SNP) | VAF 43/285 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); catalogued as COSV71729637; called by muse, mutect2, varscan2
- ZBTB37 | c.184T>C p.S62P | Missense Mutation (SNP) | VAF 37/196 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV62933717; called by muse, mutect2, varscan2
- ZDHHC9 | c.518G>T p.G173V | Missense Mutation (SNP) | VAF 33/329 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100852305; called by muse, mutect2, varscan2
- ZFHX3 | c.7297G>A p.A2433T | Missense Mutation (SNP) | VAF 25/252 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV51727953; called by muse, mutect2, varscan2
- ZMAT4 | c.236T>A p.L79H | Missense Mutation (SNP) | VAF 35/328 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52707660; called by muse, mutect2, varscan2
- ZNF14 | c.80A>G p.K27R | Missense Mutation (SNP) | VAF 44/403 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.271); catalogued as rs139981590; called by muse, mutect2, varscan2
- ZNF155 | c.658C>T p.Q220* | Nonsense Mutation (SNP) | VAF 42/381 reads (11%) | catalogued as rs764863461, COSV54207890; called by muse, mutect2, varscan2
- ZNF207 | c.320del p.K107Rfs*57 | Frame Shift Del (DEL) | VAF 7/69 reads (10%) | catalogued as rs748924817, COSV58300448, COSV58302045; called by mutect2, pindel, varscan2
- ZNF229 | c.2390C>T p.T797M | Missense Mutation (SNP) | VAF 41/237 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs778421395, COSV52161234; called by muse, mutect2, varscan2
- ZNF326 | c.367G>A p.G123R | Missense Mutation (SNP) | VAF 8/223 reads (4%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.949); catalogued as rs1390596480, COSV61036764; called by muse, mutect2
- ZNF334 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 66/352 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs1364509012, COSV61618421; called by muse, mutect2, varscan2
- ZNF43 | c.1849A>G p.T617A | Missense Mutation (SNP) | VAF 50/167 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV61684359; called by muse, mutect2, varscan2
- ZNF550 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 32/299 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.036); catalogued as rs1238555052, COSV57306722; called by muse, mutect2, varscan2
- ZNF559-ZNF177 | c.316del p.T106Hfs*5 | Frame Shift Del (DEL) | VAF 29/267 reads (11%) | catalogued as COSV58672905; called by mutect2, pindel, varscan2
- ZNF615 | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 80/275 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.787); catalogued as rs748566184, COSV65034387; called by muse, mutect2, varscan2
- ZNF770 | c.103C>T p.H35Y | Missense Mutation (SNP) | VAF 51/233 reads (22%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.643); catalogued as rs773825007, COSV62544668; called by muse, mutect2, varscan2
- ZNF792 | c.1307G>A p.S436N | Missense Mutation (SNP) | VAF 26/221 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV68693934; called by muse, mutect2, varscan2
- ZNF862 | c.2753A>G p.Q918R | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV56225113; called by muse, mutect2, varscan2
- ZSCAN21 | c.1027C>T p.Q343* | Nonsense Mutation (SNP) | VAF 7/86 reads (8%) | catalogued as COSV99461323; called by muse, mutect2
- ACACA | c.3575G>A p.R1192Q | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- ACTL7B | c.512dup p.G172Rfs*57 | Frame Shift Ins (INS) | VAF 4/21 reads (19%) | called by mutect2, pindel, varscan2
- AKAP8 | c.1244_1245del p.K415Rfs*27 | Frame Shift Del (DEL) | VAF 43/402 reads (11%) | called by mutect2, pindel, varscan2
- ANKAR | c.583del p.S195Qfs*8 | Frame Shift Del (DEL) | VAF 5/50 reads (10%) | called by mutect2, pindel
- ASH1L | c.3665del p.K1222Rfs*11 | Frame Shift Del (DEL) | VAF 94/372 reads (25%) | called by mutect2, pindel, varscan2
- ATG5 | c.704del p.K235Rfs*4 | Frame Shift Del (DEL) | VAF 35/308 reads (11%) | called by mutect2, pindel, varscan2
- BAZ2B | c.6479del p.K2160Sfs*8 | Frame Shift Del (DEL) | VAF 61/231 reads (26%) | called by mutect2, pindel, varscan2
- BCAR1 | c.1853del p.G618Vfs*84 | Frame Shift Del (DEL) | VAF 5/23 reads (22%) | called by mutect2, pindel
- BCL2L14 | c.782dup p.E262Rfs*10 | Frame Shift Ins (INS) | VAF 48/182 reads (26%) | called by mutect2, pindel, varscan2
- C7orf57 | c.640del p.S214Pfs*85 | Frame Shift Del (DEL) | VAF 9/75 reads (12%) | called by mutect2, pindel, varscan2
- CACNA1F | c.1487del p.T496Nfs*4 | Frame Shift Del (DEL) | VAF 16/151 reads (11%) | called by mutect2, varscan2
- CADPS2 | c.859del p.M287Wfs*11 | Frame Shift Del (DEL) | VAF 49/289 reads (17%) | called by mutect2, pindel, varscan2
- CDH9 | c.1925dup p.E643Gfs*20 | Frame Shift Ins (INS) | VAF 46/199 reads (23%) | called by mutect2, pindel, varscan2
- CEP350 | c.8666del p.N2889Ifs*10 | Frame Shift Del (DEL) | VAF 71/244 reads (29%) | called by mutect2, pindel, varscan2
- CSMD1 | c.9725dup p.R3243Qfs*72 (on ENST00000520002; = p.R3242Qfs*72 on NM_033225.6) | Frame Shift Ins (INS) | VAF 46/250 reads (18%) | called by mutect2, varscan2
- DENND5A | c.707dup p.P237Sfs*5 | Frame Shift Ins (INS) | VAF 28/164 reads (17%) | called by mutect2, pindel, varscan2
- DSE | c.22del p.A8Lfs*25 | Frame Shift Del (DEL) | VAF 37/152 reads (24%) | called by mutect2, pindel, varscan2
- EME1 | c.1075_1076del p.L359Vfs*26 | Frame Shift Del (DEL) | VAF 26/145 reads (18%) | called by pindel, varscan2
- ESPNL | c.614G>A p.G205D | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- EXOC2 | c.25del p.V10* | Frame Shift Del (DEL) | VAF 16/122 reads (13%) | called by mutect2, pindel, varscan2
- FAM117B | c.1144del p.V383Yfs*120 | Frame Shift Del (DEL) | VAF 23/191 reads (12%) | called by mutect2, pindel, varscan2
- FAM153B | c.143G>A p.G48D | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0.013); called by mutect2, varscan2
- FBXW7 | c.2001del p.S668Vfs*39 (on ENST00000281708 / NM_001349798.2; = p.S588Vfs*39 on NM_018315.5) | Frame Shift Del (DEL) | VAF 139/533 reads (26%) | called by mutect2, pindel, varscan2
- GPC2 | c.557del p.P186Lfs*32 | Frame Shift Del (DEL) | VAF 7/68 reads (10%) | called by mutect2, pindel, varscan2
- HERC6 | c.1988del p.K663Rfs*27 | Frame Shift Del (DEL) | VAF 16/138 reads (12%) | called by mutect2, pindel, varscan2
- HOXD3 | c.1163dup p.D388Efs*114 | Frame Shift Ins (INS) | VAF 18/50 reads (36%) | called by mutect2, pindel, varscan2
- HRG | c.599_600del p.V200Afs*25 | Frame Shift Del (DEL) | VAF 55/397 reads (14%) | called by pindel, varscan2
- INPP4B | c.210del p.V71Wfs*5 | Frame Shift Del (DEL) | VAF 20/166 reads (12%) | called by mutect2, pindel, varscan2
- INTS8 | c.1778_1779del p.F593Cfs*21 | Frame Shift Del (DEL) | VAF 44/380 reads (12%) | called by mutect2, pindel, varscan2
- JHY | c.1574del p.N525Ifs*17 | Frame Shift Del (DEL) | VAF 6/67 reads (9%) | called by mutect2, pindel
- KIF13A | c.1617del p.F539Lfs*3 | Frame Shift Del (DEL) | VAF 16/143 reads (11%) | called by mutect2, pindel, varscan2
- KIFC1 | c.986del p.P329Lfs*32 | Frame Shift Del (DEL) | VAF 5/34 reads (15%) | called by mutect2, pindel, varscan2
- KLHL13 | c.1740dup p.G581Wfs*8 | Frame Shift Ins (INS) | VAF 75/522 reads (14%) | called by mutect2, pindel, varscan2
- LRRIQ1 | c.2153del p.N718Mfs*8 | Frame Shift Del (DEL) | VAF 21/75 reads (28%) | called by mutect2, pindel, varscan2
- MAP3K13 | c.1265_1268del p.Y422Sfs*11 | Frame Shift Del (DEL) | VAF 26/218 reads (12%) | called by pindel, varscan2
- MAP3K2 | c.120del p.K40Nfs*29 | Frame Shift Del (DEL) | VAF 27/246 reads (11%) | called by mutect2, varscan2
- MAPK7 | c.2320_2321dup p.A775Qfs*14 | Frame Shift Ins (INS) | VAF 19/94 reads (20%) | called by mutect2, varscan2
- MAPKBP1 | c.4224G>T p.Q1408H (on ENST00000456763 / NM_001128608.2; = p.Q1402H on NM_014994.3) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.332); called by muse, mutect2
- MBD6 | c.2012del p.P671Lfs*4 | Frame Shift Del (DEL) | VAF 6/61 reads (10%) | called by pindel, varscan2
- MDGA2 | c.1172dup p.S392Vfs*25 (on ENST00000399232 / NM_001113498.2; = p.S94Vfs*25 on NM_182830.4) | Frame Shift Ins (INS) | VAF 53/176 reads (30%) | called by mutect2, pindel, varscan2
- MINDY3 | c.1107del p.P370Lfs*19 | Frame Shift Del (DEL) | VAF 27/173 reads (16%) | called by mutect2, pindel, varscan2
- MLH3 | c.2021del p.N674Ifs*6 | Frame Shift Del (DEL) | VAF 31/177 reads (18%) | called by mutect2, varscan2
- MPP5 | c.1340del p.K447Rfs*18 | Frame Shift Del (DEL) | VAF 81/327 reads (25%) | called by mutect2, pindel, varscan2
- MPRIP | c.1058del p.P353Qfs*30 | Frame Shift Del (DEL) | VAF 11/63 reads (17%) | called by mutect2, pindel, varscan2
- MTCL1 | c.2080del p.L694Cfs*5 (on ENST00000306329 / NM_001378206.1; = p.L334Cfs*5 on NM_015210.4) | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- MTG1 | c.986del p.P329Rfs*28 | Frame Shift Del (DEL) | VAF 14/61 reads (23%) | called by mutect2, pindel, varscan2
- NHS | c.766del p.L256Ffs*28 | Frame Shift Del (DEL) | VAF 30/125 reads (24%) | called by mutect2, pindel, varscan2
- NLGN3 | c.2341del p.H781Mfs*14 (on ENST00000358741 / NM_181303.2; = p.H761Mfs*14 on NM_018977.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 34/121 reads (28%) | called by mutect2, pindel, varscan2
- OPTN | c.345del p.K117Nfs*32 | Frame Shift Del (DEL) | VAF 74/336 reads (22%) | called by pindel, varscan2
- OR2L3 | c.816dup p.L273Sfs*18 | Frame Shift Ins (INS) | VAF 30/269 reads (11%) | called by mutect2, varscan2
- PHF20L1 | c.893del p.K298Rfs*66 | Frame Shift Del (DEL) | VAF 73/577 reads (13%) | called by mutect2, pindel, varscan2
- PIWIL2 | c.700_701del p.Q234Vfs*3 | Frame Shift Del (DEL) | VAF 53/310 reads (17%) | called by pindel, varscan2
- PLBD1 | c.641del p.N214Tfs*4 | Frame Shift Del (DEL) | VAF 33/266 reads (12%) | called by mutect2, pindel, varscan2
- PLEC | c.7732_7733del p.S2578* (on ENST00000322810 / NM_201380.4; = p.S2468* on NM_000445.5) | Frame Shift Del (DEL) | VAF 8/72 reads (11%) | called by pindel, varscan2
- PLEKHA6 | c.982del p.V328Yfs*172 | Frame Shift Del (DEL) | VAF 16/118 reads (14%) | called by mutect2, pindel, varscan2
- PNRC1 | c.752del p.K251Sfs*14 | Frame Shift Del (DEL) | VAF 31/104 reads (30%) | called by mutect2, pindel, varscan2
- POU2F2 | c.187-3del | Splice Region (DEL) | VAF 12/98 reads (12%) | called by mutect2, pindel
- PSMB6 | c.455del p.G152Vfs*2 | Frame Shift Del (DEL) | VAF 13/81 reads (16%) | called by mutect2, pindel, varscan2
- PSMD3 | c.1201_1203del p.N401del | In Frame Del (DEL) | VAF 28/241 reads (12%) | called by mutect2, pindel, varscan2
- PTCH1 | c.3606del p.S1203Afs*52 | Frame Shift Del (DEL) | VAF 16/100 reads (16%) | called by mutect2, pindel, varscan2
- PTEN | c.628dup p.T210Nfs*33 | Frame Shift Ins (INS) | VAF 44/195 reads (23%) | called by mutect2, pindel, varscan2
- PTPN12 | c.2135del p.K712Sfs*5 | Frame Shift Del (DEL) | VAF 26/116 reads (22%) | called by mutect2, varscan2
- RAB3GAP2 | c.3102del p.F1034Lfs*5 | Frame Shift Del (DEL) | VAF 74/282 reads (26%) | called by mutect2, pindel, varscan2
- RAD23A | c.694del p.L232Wfs*16 | Frame Shift Del (DEL) | VAF 18/73 reads (25%) | called by mutect2, pindel, varscan2
- RARB | c.245del p.P82Lfs*39 (on ENST00000383772 / NM_001290216.2; = p.P75Lfs*39 on NM_000965.5 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 51/351 reads (15%) | called by mutect2, pindel, varscan2
- RERE | c.1246_1248del p.F416del | In Frame Del (DEL) | VAF 72/308 reads (23%) | called by pindel, varscan2
- S1PR3 | c.200dup p.N67Kfs*3 | Frame Shift Ins (INS) | VAF 6/43 reads (14%) | called by mutect2, pindel, varscan2
- SETD5 | c.3855del p.S1286Lfs*84 | Frame Shift Del (DEL) | VAF 24/111 reads (22%) | called by mutect2, pindel, varscan2
- SF3A1 | c.1935del p.M646* | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | called by mutect2, pindel, varscan2
- SH3PXD2A | c.328del p.H110Tfs*47 | Frame Shift Del (DEL) | VAF 13/62 reads (21%) | called by mutect2, pindel, varscan2
- SLC16A9 | c.604del p.I202* | Frame Shift Del (DEL) | VAF 42/215 reads (20%) | called by mutect2, pindel, varscan2
- SRPX | c.677del p.P226Qfs*32 | Frame Shift Del (DEL) | VAF 36/326 reads (11%) | called by mutect2, pindel, varscan2
- SUN5 | c.616del p.A206Pfs*35 | Frame Shift Del (DEL) | VAF 14/124 reads (11%) | called by mutect2, pindel, varscan2
- TADA2A | c.818A>G p.H273R | Missense Mutation (SNP) | VAF 133/517 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TASOR2 | c.3176del p.N1059Mfs*11 | Frame Shift Del (DEL) | VAF 33/181 reads (18%) | called by mutect2, pindel, varscan2
- TGS1 | c.525dup p.D176Rfs*3 | Frame Shift Ins (INS) | VAF 23/177 reads (13%) | called by mutect2, pindel, varscan2
- TRAM1L1 | c.1033del p.R345Efs*14 | Frame Shift Del (DEL) | VAF 40/380 reads (11%) | called by mutect2, pindel, varscan2
- TTC14 | c.1770dup p.G591Wfs*3 | Frame Shift Ins (INS) | VAF 23/89 reads (26%) | called by mutect2, pindel, varscan2
- TXK | c.620del p.K207Rfs*21 | Frame Shift Del (DEL) | VAF 28/288 reads (10%) | called by pindel, varscan2
- UBAC2 | c.424del p.Y142Tfs*23 (on ENST00000403766 / NM_001144072.2; = p.Y107Tfs*23 on NM_177967.4) | Frame Shift Del (DEL) | VAF 80/332 reads (24%) | called by mutect2, pindel, varscan2
- UNC79 | c.6543del p.F2181Lfs*10 (on ENST00000393151 / NM_001346218.2; = p.F2004Lfs*10 on NM_020818.5) | Frame Shift Del (DEL) | VAF 38/384 reads (10%) | called by mutect2, pindel
- WNK2 | c.2785del p.H929Ifs*7 | Frame Shift Del (DEL) | VAF 39/137 reads (28%) | called by mutect2, pindel, varscan2
- WWC2 | c.616del p.M206Cfs*17 | Frame Shift Del (DEL) | VAF 14/106 reads (13%) | called by mutect2, pindel, varscan2
- ZDBF2 | c.3280del p.I1094* | Frame Shift Del (DEL) | VAF 21/101 reads (21%) | called by mutect2, pindel, varscan2
- ZNF532 | c.449del p.P150Lfs*15 | Frame Shift Del (DEL) | VAF 8/84 reads (10%) | called by mutect2, pindel
- ZNF536 | c.2834del p.P945Lfs*3 | Frame Shift Del (DEL) | VAF 10/62 reads (16%) | called by mutect2, pindel, varscan2
- ZNF567 | c.730del p.R244Efs*25 (on ENST00000536254 / NM_001322913.1; = p.R213Efs*25 on NM_152603.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | called by mutect2, pindel, varscan2
- ZNF831 | c.3542del p.P1181Rfs*8 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | called by mutect2, pindel, varscan2
- ZNF84 | c.2211del p.K737Nfs*11 | Frame Shift Del (DEL) | VAF 148/596 reads (25%) | called by mutect2, pindel, varscan2
- ADGRG2 | c.123T>C p.D41= | Silent (SNP) | VAF 121/346 reads (35%) | catalogued as COSV61340345; called by muse, mutect2, varscan2
- AFG3L2 | c.2319A>G p.P773= | Silent (SNP) | VAF 28/270 reads (10%) | catalogued as COSV52316307; called by muse, mutect2, varscan2
- ALOXE3 | c.1122T>C p.P374= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs1238956689, COSV59076900; called by muse, mutect2, varscan2
- AP5M1 | c.945C>T p.S315= | Silent (SNP) | VAF 36/344 reads (10%) | catalogued as COSV99841388; called by muse, mutect2
- ARMC5 | c.1038G>A p.Q346= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV51658537; called by muse, mutect2, varscan2
- ATIC | c.1053G>A p.L351= | Silent (SNP) | VAF 28/200 reads (14%) | catalogued as COSV52694481, COSV99377488; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1758G>A p.L586= | Silent (SNP) | VAF 35/332 reads (11%) | catalogued as COSV59478279, COSV59481535; called by muse, mutect2, varscan2
- BCAT2 | c.936G>C p.R312= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs773962524, COSV60273374; called by muse, mutect2, varscan2
- BOC | c.2982G>A p.P994= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as rs200237762, COSV56353688; called by muse, mutect2, varscan2
- BRD9 | c.1107G>A p.T369= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as rs752571775, COSV60248504; called by mutect2, varscan2
- CASP8 | c.1170G>A p.T390= (on ENST00000432109 / NM_033355.3; = p.T407= on NM_001228.4) | Silent (SNP) | VAF 11/104 reads (11%) | catalogued as rs539029508, COSV51855591; called by muse, mutect2, varscan2
- CATSPER3 | c.591C>T p.C197= | Silent (SNP) | VAF 32/261 reads (12%) | catalogued as COSV50948052; called by muse, mutect2, varscan2
- CCDC40 | c.1071C>T p.S357= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs757089648, COSV53902187; called by muse, mutect2, varscan2
- CCN3 | c.345C>T p.V115= | Silent (SNP) | VAF 28/318 reads (9%) | catalogued as COSV52386080; called by muse, mutect2
- CCNE2 | c.1167C>T p.G389= | Silent (SNP) | VAF 66/962 reads (7%) | catalogued as rs1413340631, COSV100353901; called by muse, mutect2
- CDH18 | c.291T>C p.A97= | Silent (SNP) | VAF 16/310 reads (5%) | catalogued as COSV56929632; called by muse, mutect2
- CDH23 | c.2832C>T p.S944= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs775998990, COSV54944260; called by muse, mutect2, varscan2
- CFAP94 | c.166C>A p.R56= (on ENST00000320267 / NM_001352064.2; = p.R62= on NM_018272.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 109/556 reads (20%) | catalogued as COSV57234824; called by muse, mutect2, varscan2
- CHD9 | c.6963C>A p.A2321= | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as COSV99529825; called by muse, mutect2, varscan2
- CHIA | c.168C>T p.Y56= | Silent (SNP) | VAF 22/201 reads (11%) | catalogued as rs370883122; called by muse, mutect2, varscan2
- CHMP2B | c.219G>T p.T73= | Silent (SNP) | VAF 13/180 reads (7%) | catalogued as COSV99773712; called by muse, mutect2
- CIB3 | c.408G>A p.T136= | Silent (SNP) | VAF 96/325 reads (30%) | catalogued as rs1288188374, COSV54166059; called by muse, mutect2, varscan2
- CIT | c.2847G>A p.L949= | Silent (SNP) | VAF 38/458 reads (8%) | catalogued as COSV99951128; called by muse, mutect2
- CLCN5 | c.342C>T p.D114= | Silent (SNP) | VAF 66/414 reads (16%) | catalogued as COSV56585674; called by muse, mutect2, varscan2
- CNTN3 | c.2439C>T p.S813= | Silent (SNP) | VAF 60/208 reads (29%) | catalogued as COSV55179008; called by muse, mutect2, varscan2
- COL25A1 | c.1488A>G p.K496= | Silent (SNP) | VAF 28/275 reads (10%) | catalogued as COSV101211681; called by muse, mutect2
- COL4A3 | c.4677C>T p.A1559= | Silent (SNP) | VAF 32/210 reads (15%) | catalogued as rs764663555, COSV67414241; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A3 | c.414C>T p.A138= | Silent (SNP) | VAF 18/149 reads (12%) | catalogued as rs148996231; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- CPLANE2 | c.153T>C p.I51= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV65057227; called by muse, mutect2, varscan2
- CPNE3 | c.1371A>G p.G457= | Silent (SNP) | VAF 79/392 reads (20%) | catalogued as COSV52208514; called by muse, mutect2, varscan2
- CRNN | c.1074G>A p.V358= | Silent (SNP) | VAF 73/267 reads (27%) | catalogued as COSV55123015; called by muse, mutect2, varscan2
- CTAG2 | c.141C>T p.G47= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs782629684, COSV99909216; called by muse, mutect2, varscan2
- CUL9 | c.612C>T p.V204= | Silent (SNP) | VAF 18/155 reads (12%) | catalogued as rs769262435, COSV52731871; called by muse, mutect2, varscan2
- DBF4 | c.825C>T p.G275= | Silent (SNP) | VAF 63/267 reads (24%) | catalogued as rs766241590, COSV55998091; called by muse, mutect2, varscan2
- DBF4B | c.429C>T p.S143= | Silent (SNP) | VAF 7/177 reads (4%) | catalogued as COSV100154735; called by muse, mutect2
- DCAF4L2 | c.403C>T p.L135= | Silent (SNP) | VAF 26/240 reads (11%) | catalogued as COSV60476356, COSV60480625; called by muse, mutect2, varscan2
- DDX54 | c.825G>A p.V275= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV58375103; called by muse, mutect2, varscan2
- DEPDC1 | c.2106G>A p.K702= (on ENST00000456315 / NM_001114120.3; = p.K418= on NM_017779.6) | Silent (SNP) | VAF 13/434 reads (3%) | catalogued as rs1177019583, COSV100920499, COSV63957717; called by muse, mutect2
- DHX30 | c.3312C>T p.D1104= (on ENST00000445061 / NM_138615.3; = p.D1065= on NM_014966.3) | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs112195130, COSV99276430; called by muse, mutect2, varscan2
- DIXDC1 | c.1347T>C p.S449= (on ENST00000440460 / NM_001037954.4; = p.S238= on NM_033425.4) | Silent (SNP) | VAF 40/163 reads (25%) | catalogued as rs781913557, COSV59462761; called by muse, mutect2, varscan2
- DLL4 | c.1491C>T p.T497= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as rs1002658065, COSV51067046, COSV99989748; called by muse, mutect2, varscan2
- DMBX1 | c.531T>A p.A177= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV63602356; called by muse, mutect2, varscan2
- DNAH5 | c.3942C>T p.G1314= | Silent (SNP) | VAF 57/226 reads (25%) | catalogued as rs764970736, COSV54227337; called by muse, mutect2, varscan2
- DNM1L | c.855T>C p.L285= | Silent (SNP) | VAF 32/267 reads (12%) | catalogued as COSV56776253; called by muse, mutect2, varscan2
- DOCK8 | c.1908C>T p.P636= | Silent (SNP) | VAF 7/183 reads (4%) | catalogued as rs1341756091; called by muse, mutect2
- DYNC1H1 | c.10356C>T p.A3452= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as rs758827732, COSV64139772; ClinVar: likely benign; called by muse, mutect2, varscan2
- EP300 | c.2124A>G p.P708= | Silent (SNP) | VAF 20/160 reads (13%) | catalogued as COSV54339407; called by muse, mutect2, varscan2
- EXTL1 | c.384T>C p.P128= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV65338012; called by muse, varscan2
- FCRL3 | c.1563G>A p.S521= | Silent (SNP) | VAF 30/135 reads (22%) | catalogued as rs772982173, COSV63841237; called by muse, mutect2, varscan2
- FREM2 | c.1857T>C p.H619= | Silent (SNP) | VAF 56/414 reads (14%) | catalogued as rs370751010; called by muse, mutect2, varscan2
- GMNN | c.558G>T p.V186= | Silent (SNP) | VAF 22/176 reads (13%) | catalogued as COSV57777265; called by muse, mutect2, varscan2
- IGHV3-7 | c.291A>G p.S97= | Silent (SNP) | VAF 46/441 reads (10%) | catalogued as rs782460099; called by muse, mutect2
- IGKV1D-8 | c.333A>G p.Q111= | Silent (SNP) | VAF 80/585 reads (14%) | called by muse, mutect2, varscan2
- INPP5D | c.2961G>A p.R987= (on ENST00000445964 / NM_001017915.3; = p.R986= on NM_005541.5) | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV100856757, COSV64038812; called by muse, mutect2, varscan2
- ITPR1 | c.5664C>T p.D1888= (on ENST00000354582; = p.D1833= on NM_002222.7) | Silent (SNP) | VAF 28/207 reads (14%) | catalogued as rs367889492; called by muse, mutect2, varscan2
- KCNA4 | c.1071C>A p.P357= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as COSV60253314; called by muse, mutect2, varscan2
- KCNQ2 | c.822G>A p.T274= | Silent (SNP) | VAF 11/92 reads (12%) | catalogued as rs377485599, COSV60434539; called by muse, mutect2, varscan2
- KIAA0100 | c.1206T>C p.P402= | Silent (SNP) | VAF 36/275 reads (13%) | catalogued as COSV66495118; called by muse, varscan2
- KLHL25 | c.348C>T p.N116= | Silent (SNP) | VAF 25/98 reads (26%) | catalogued as rs144919185; called by muse, mutect2
- KLHL42 | c.1185C>T p.I395= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV67146059; called by muse, mutect2
- KPNB1 | c.2070C>T p.D690= | Silent (SNP) | VAF 115/355 reads (32%) | catalogued as rs371651425; called by muse, mutect2, varscan2
- LAMP2 | c.159C>T p.R53= | Silent (SNP) | VAF 23/147 reads (16%) | catalogued as COSV99568938; called by muse, mutect2
- LPA | c.4854T>C p.H1618= | Silent (SNP) | VAF 90/611 reads (15%) | catalogued as COSV60306315; called by muse, mutect2, varscan2
- LYZL6 | c.304C>T p.L102= | Silent (SNP) | VAF 21/115 reads (18%) | called by muse, mutect2, varscan2
- MAGEC1 | c.1551T>C p.P517= | Silent (SNP) | VAF 54/267 reads (20%) | catalogued as COSV53577581; called by muse, mutect2, varscan2
- MAPT | c.2013T>C p.N671= (on ENST00000262410 / NM_001377265.1; = p.N279= on NM_005910.5) | Silent (SNP) | VAF 54/150 reads (36%) | catalogued as CM981234, COSV52244188; called by muse, mutect2, varscan2
- MFF | c.570A>T p.A190= | Silent (SNP) | VAF 44/172 reads (26%) | catalogued as COSV58826366; called by muse, mutect2, varscan2
- MID1 | c.228C>T p.N76= | Silent (SNP) | VAF 22/136 reads (16%) | catalogued as COSV58193080; called by muse, mutect2, varscan2
- MKI67 | c.7125A>G p.A2375= | Silent (SNP) | VAF 102/963 reads (11%) | catalogued as COSV64075673; called by muse, mutect2, varscan2
- MRGPRX4 | c.342C>T p.S114= | Silent (SNP) | VAF 38/284 reads (13%) | catalogued as rs774403101, COSV58591158; called by muse, mutect2, varscan2
- MUC5B | c.15063C>T p.T5021= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV71594269; called by muse, mutect2, varscan2
- NBEA | c.3804C>T p.D1268= | Silent (SNP) | VAF 19/115 reads (17%) | catalogued as rs949121350, COSV59795817; called by muse, mutect2, varscan2
- NBPF9 | c.1761A>G p.S587= | Silent (SNP) | VAF 37/360 reads (10%) | catalogued as COSV56019611; called by muse, mutect2, varscan2
- NDUFB3 | c.246A>G p.V82= | Silent (SNP) | VAF 167/560 reads (30%) | catalogued as COSV52987879; called by muse, mutect2, varscan2
- NOSIP | c.831G>A p.Q277= | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as COSV59199653; called by muse, mutect2, varscan2
- NOTCH3 | c.4560G>A p.P1520= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as rs370010007, COSV54642424; called by muse, mutect2, varscan2
- NPRL3 | c.1047C>T p.A349= (on ENST00000611875 / NM_001077350.3; = p.A324= on NM_001039476.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 38/108 reads (35%) | catalogued as rs373353333; called by muse, mutect2, varscan2
- OGFOD1 | c.81G>T p.S27= | Silent (SNP) | VAF 13/119 reads (11%) | catalogued as COSV55860430; called by muse, mutect2, varscan2
- PCARE | c.2239C>T p.L747= | Silent (SNP) | VAF 22/127 reads (17%) | catalogued as rs1163582847, COSV59056385; called by muse, mutect2, varscan2
- PDE1C | c.435A>G p.R145= | Silent (SNP) | VAF 24/312 reads (8%) | catalogued as COSV100374003; called by muse, mutect2
- PHACTR3 | c.996C>T p.S332= | Silent (SNP) | VAF 44/267 reads (16%) | catalogued as rs760921402, COSV63031467; called by muse, varscan2
- PHKG1 | c.753G>A p.S251= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs547904081, COSV51917955; called by muse, mutect2, varscan2
- PLEKHM2 | c.2001G>A p.Q667= | Silent (SNP) | VAF 20/129 reads (16%) | catalogued as COSV65397316; called by muse, mutect2, varscan2
- PLRG1 | c.753C>T p.G251= | Silent (SNP) | VAF 37/226 reads (16%) | catalogued as rs760981440, COSV57424262; called by muse, mutect2, varscan2
- PPP2R5C | c.1431C>T p.D477= | Silent (SNP) | VAF 53/221 reads (24%) | catalogued as rs779324359, COSV58272235; called by muse, mutect2, varscan2
- PRKAB1 | c.711C>T p.N237= | Silent (SNP) | VAF 38/345 reads (11%) | catalogued as COSV57555334; called by muse, mutect2
- PTMS | c.204A>G p.E68= | Silent (SNP) | VAF 26/129 reads (20%) | catalogued as COSV52566439; called by muse, mutect2, varscan2
- PTPN23 | c.789G>A p.Q263= | Silent (SNP) | VAF 17/120 reads (14%) | catalogued as COSV55546431; called by muse, mutect2, varscan2
- PXYLP1 | c.732C>T p.S244= | Silent (SNP) | VAF 14/114 reads (12%) | catalogued as COSV53892091; called by muse, mutect2, varscan2
- QRICH2 | c.4911G>A p.P1637= | Silent (SNP) | VAF 14/154 reads (9%) | catalogued as rs372521868; called by muse, mutect2
- RABIF | c.165T>C p.S55= | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as COSV66131771; called by muse, mutect2, varscan2
- RBBP9 | c.135C>T p.P45= | Silent (SNP) | VAF 52/205 reads (25%) | catalogued as rs142061709; called by muse, mutect2, varscan2
- RBM4 | c.138G>A p.T46= | Silent (SNP) | VAF 37/319 reads (12%) | catalogued as COSV59519709; called by muse, mutect2, varscan2
- RIMBP2 | c.1854C>T p.H618= | Silent (SNP) | VAF 29/129 reads (22%) | catalogued as rs774732133, COSV55476240; called by muse, mutect2, varscan2
- RO60 | c.1263A>G p.P421= | Silent (SNP) | VAF 30/293 reads (10%) | catalogued as COSV66474437; called by muse, mutect2, varscan2
- ROS1 | c.4686G>A p.Q1562= | Silent (SNP) | VAF 108/355 reads (30%) | catalogued as COSV63858845; called by muse, mutect2, varscan2
- RP1L1 | c.5349G>A p.A1783= | Silent (SNP) | VAF 124/485 reads (26%) | catalogued as rs773065990, COSV66753685, COSV66761067; called by muse, mutect2, varscan2
- RPS6KA3 | c.1593C>T p.H531= | Silent (SNP) | VAF 36/344 reads (10%) | catalogued as rs757920979, COSV65388762; called by muse, mutect2, varscan2
- SDK1 | c.5907G>A p.R1969= | Silent (SNP) | VAF 15/99 reads (15%) | catalogued as COSV67380700; called by muse, mutect2, varscan2
- SLC23A1 | c.615C>T p.D205= | Silent (SNP) | VAF 27/131 reads (21%) | catalogued as COSV62297202; called by muse, mutect2, varscan2
- SLC25A41 | c.684C>T p.C228= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as rs367698881, COSV58600399; called by muse, mutect2, varscan2
- SLCO4C1 | c.1194T>C p.T398= | Silent (SNP) | VAF 8/102 reads (8%) | catalogued as COSV100195916; called by muse, mutect2
- SLITRK3 | c.2463A>C p.A821= | Silent (SNP) | VAF 49/181 reads (27%) | catalogued as COSV53851170; called by muse, varscan2
- SMARCC1 | c.2883G>A p.Q961= | Silent (SNP) | VAF 68/556 reads (12%) | catalogued as COSV54383692; called by muse, mutect2, varscan2
- SNED1 | c.2706C>T p.C902= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs764256373, COSV60030491; called by muse, mutect2
- SON | c.3156T>C p.P1052= | Silent (SNP) | VAF 12/154 reads (8%) | catalogued as COSV99280057; called by muse, mutect2
- SOX4 | c.277C>T p.L93= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs1348893318, COSV55193563; called by muse, mutect2, varscan2
- SPAM1 | c.804G>A p.Q268= | Silent (SNP) | VAF 26/184 reads (14%) | catalogued as COSV56145430; called by muse, mutect2, varscan2
- STXBP5 | c.147C>T p.C49= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV51655500; called by muse, mutect2, varscan2
- SUPT20HL1 | c.150A>G p.K50= | Silent (SNP) | VAF 21/369 reads (6%) | called by muse, mutect2
- SYPL2 | c.297G>A p.E99= | Silent (SNP) | VAF 51/228 reads (22%) | catalogued as COSV63995176; called by muse, mutect2, varscan2
- TENM3 | c.5577A>G p.T1859= | Silent (SNP) | VAF 74/255 reads (29%) | catalogued as rs1404243922, COSV69314414; called by muse, mutect2, varscan2
- TG | c.7593C>T p.G2531= | Silent (SNP) | VAF 23/197 reads (12%) | catalogued as rs766820808, COSV55072968, COSV55074990; called by muse, mutect2, varscan2
- THBD | c.1632C>T p.G544= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV65702910; called by muse, mutect2, varscan2
- TLE1 | c.1383T>C p.F461= | Silent (SNP) | VAF 14/241 reads (6%) | catalogued as rs1275001775, COSV100918995; called by muse, mutect2
- TMEM170A | c.363C>A p.A121= | Silent (SNP) | VAF 37/300 reads (12%) | catalogued as COSV62923261; called by muse, mutect2, varscan2
- TOGARAM2 | c.409T>C p.L137= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV65422892; called by muse, mutect2, varscan2
- TP73 | c.1467C>T p.A489= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as rs1014008675, COSV60704255; called by muse, mutect2, varscan2
- TRAP1 | c.1224C>T p.S408= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as rs377663088; called by muse, mutect2
- TSC1 | c.3180C>T p.S1060= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as COSV53770628; called by muse, mutect2, varscan2
- TTN | c.90762C>T p.S30254= (on ENST00000591111; = p.S22830= on NM_003319.4) | Silent (SNP) | VAF 33/205 reads (16%) | catalogued as COSV60213285; called by muse, mutect2, varscan2
- UHRF1BP1 | c.1479C>A p.S493= | Silent (SNP) | VAF 91/305 reads (30%) | catalogued as COSV51958356; called by muse, mutect2, varscan2
- USP47 | c.2988G>T p.T996= (on ENST00000399455 / NM_001372095.1; = p.T908= on NM_017944.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 48/393 reads (12%) | catalogued as COSV60462392, COSV60466068; called by muse, mutect2, varscan2
- USP9X | c.4533C>T p.G1511= | Silent (SNP) | VAF 26/244 reads (11%) | catalogued as COSV61072646; called by muse, mutect2, varscan2
- VGLL3 | c.171C>A p.V57= | Silent (SNP) | VAF 41/128 reads (32%) | catalogued as COSV67353868; called by muse, mutect2, varscan2
- VWF | c.5223T>C p.I1741= | Silent (SNP) | VAF 19/140 reads (14%) | catalogued as COSV54628246; called by muse, mutect2, varscan2
- ZNF134 | c.144G>A p.T48= | Silent (SNP) | VAF 15/163 reads (9%) | catalogued as rs770430334, COSV68696582; called by muse, mutect2
- ZNF211 | c.1197C>T p.C399= (on ENST00000347302 / NM_198855.4; = p.C412= on NM_006385.5) | Silent (SNP) | VAF 24/210 reads (11%) | catalogued as COSV53743980; called by muse, mutect2, varscan2
- ZNF461 | c.1074A>G p.E358= | Silent (SNP) | VAF 53/278 reads (19%) | catalogued as COSV64454469; called by muse, mutect2, varscan2
- ZNF558 | c.81C>T p.G27= | Silent (SNP) | VAF 152/499 reads (30%) | catalogued as rs762746194, COSV56862727; called by muse, mutect2, varscan2
- ZRANB3 | c.1890C>T p.C630= | Silent (SNP) | VAF 34/326 reads (10%) | catalogued as COSV51508751; called by muse, mutect2
- DIRC1 | n.296G>T | RNA (SNP) | VAF 45/139 reads (32%) | catalogued as COSV100352997; called by muse, mutect2
- EZR | c.13-96C>T | Intron (SNP) | VAF 12/58 reads (21%) | catalogued as rs113860686; called by muse, mutect2
- LRP5L | n.634C>T | RNA (SNP) | VAF 48/269 reads (18%) | catalogued as rs150219610; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85936A>G | Intron (SNP) | VAF 10/287 reads (3%) | catalogued as COSV72278227; called by muse, mutect2
- OBSCN | c.5138-255del | Intron (DEL) | VAF 6/76 reads (8%) | called by mutect2, pindel
- PLEKHG5 | c.-7C>T | 5'UTR (SNP) | VAF 25/115 reads (22%) | catalogued as rs764529582, COSV100894701, COSV66662903; called by muse, mutect2, varscan2
- SLC22A20P | n.1543C>T | RNA (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2, varscan2
- SLC35E2A | n.1199dup | RNA (INS) | VAF 5/41 reads (12%) | called by mutect2, pindel, varscan2
- SLCO1A2 | c.1675+24C>T | Intron (SNP) | VAF 9/54 reads (17%) | catalogued as COSV56606897; called by muse, mutect2, varscan2
- SSPOP | n.6666G>T | RNA (SNP) | VAF 8/29 reads (28%) | catalogued as COSV50488527; called by muse, mutect2, varscan2
- SSPOP | n.9966G>A | RNA (SNP) | VAF 7/46 reads (15%) | catalogued as COSV100948138; called by muse, mutect2
- TRAC | c.*301T>C | 3'UTR (SNP) | VAF 38/267 reads (14%) | called by muse, mutect2, varscan2
- ZFHX3 | c.-533+42G>A | Intron (SNP) | VAF 15/135 reads (11%) | catalogued as rs560022615, COSV73947930; called by muse, mutect2, varscan2
